MMRF case MMRF_2327 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a25ce687-1d4a-4c58-a010-af8c648c9f79

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.4 years (26,820 days); ISS stage: I; Days to last known disease status: 839 days (2.3 years); Days to last follow up: 839 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 263 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 39 g/L; Immunoglobulin A 0.158 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.78 ×10⁹/L; Absolute Neutrophil 5.18 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 93.7 µmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 10.2 g/dL; Glucose 8.86 mmol/L; C-Reactive Protein 0.019 mg/dL.
- Day 92: M Protein 2.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.156 mg/dL; Immunoglobulin G 27.8 g/L; Immunoglobulin A 0.076 g/L; Immunoglobulin M 0.277 g/L; Beta 2 Microglobulin 1.69 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 80.4 µmol/L; Albumin 41 g/L; Total Protein 8.3 g/dL; Glucose 8.91 mmol/L.
- Day 169 (ECOG 1): M Protein 1.99 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 25.3 g/L; Immunoglobulin A 0.067 g/L; Immunoglobulin M 0.293 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.83 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 5.61 mmol/L.
- Day 260 (ECOG 1): M Protein 2.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.22 mg/dL; Immunoglobulin G 25.6 g/L; Immunoglobulin A 0.061 g/L; Immunoglobulin M 0.185 g/L; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 59.2 µmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 5.01 mmol/L.
- Day 375 (ECOG 1): M Protein 0.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.158 g/L; Immunoglobulin M 0.253 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.58 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 53.9 µmol/L; Calcium 2.15 mmol/L; Albumin 43.9 g/L; Total Protein 6.1 g/dL; Glucose 5.28 mmol/L.
- Day 445 (ECOG 0): M Protein 0.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.164 g/L; Immunoglobulin M 0.192 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.09 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.28 mmol/L; Albumin 41.8 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 557 (ECOG 0): M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.238 g/L; Immunoglobulin M 0.165 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.14 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 63.6 µmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6 mmol/L.
- Day 613 (ECOG 0): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 8.75 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.173 g/L; Beta 2 Microglobulin 2.23 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.69 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 59 ×10⁹/L; Creatinine 150 µmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 5.56 mmol/L.
- Day 708 (ECOG 0): M Protein 0.87 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.229 g/L; Beta 2 Microglobulin 2.78 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.94 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 75.1 µmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 839 (ECOG 2): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 0.227 g/L; Immunoglobulin M 0.152 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.22 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 65.4 µmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day 1: Weight: 82 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2327_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2327_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
